Gene-level copy-number profile of tumor specimen C3N-02027-01 from CPTAC case C3N-02027, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage I; FIGO stage: Stage I; Tumor grade: G3; Age at diagnosis: 54.9 years (20,045 days).
Specimen C3N-02027-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 9879a96c-ce35-4945-803f-ba04dcc2cb86.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-02027-71 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,221 have no estimate.
https://portal.gdc.cancer.gov/files/58b6bc5f-69bc-48c4-ae37-4fa663459813

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 43; copy number 2: 58,245; copy number 3: 96; copy number 4: 14; copy number 5: 3; copy number 8: 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 4 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr15:30,103,720–30,145,567, 3 genes, copy number 5 (within-gene range 4–5): ULK4P3, U8, GOLGA8T.
- chr15:30,516,079–30,517,867, 1 gene, copy number 8: AC026150.2.

Autosomal genes at a single copy (total copy number 1): 43. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
